Gene-level copy-number profile of tumor specimen TCGA-CV-7415-01A from TCGA case TCGA-CV-7415, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.4 years (22,062 days).
Specimen TCGA-CV-7415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.bfd7b26c-a460-4d85-8f09-657a72068dc5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7415-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/902b0367-f69a-4065-a456-9f9a63ad6a1b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 458; copy number 2: 8,468; copy number 3: 22,693; copy number 4: 15,995; copy number 5: 4,968; copy number 6: 4,540; copy number 7: 1,106; copy number 8: 319; copy number 9: 874; copy number 10: 7; copy number 13: 169; copy number 15: 12; copy number 20: 34; copy number 24: 22; copy number 26: 61; copy number 45: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7415-01A-11D-2077-01): tumor purity 0.45, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,926,094–24,088,051, 84 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,608 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,763–409,417, 1 gene, copy number 7 (within-gene range 3–7): CHL1.
- chr3:308,714–846,561, 5 genes, copy number 7 (within-gene range 3–7): RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32.
- chr3:1,730,070–1,987,470, 3 genes, copy number 7: RPL23AP39, RPL21P17, AC018814.1.
- chr3:21,006,730–21,406,508, 2 genes, copy number 8: AC099753.1, VENTXP7.
- chr3:63,741,827–64,688,000, 23 genes, copy number 7: AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1.
- chr3:91,356,755–94,131,832, 12 genes, copy number 15: ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr3:161,426,427–198,222,513, 651 genes, copy number 9 (broad region; genes not listed).
- chr8:46,028,804–108,132,114, 976 genes, copy number 7 (broad region; genes not listed).
- chr9:1,151,807–1,550,103, 5 genes, copy number 8: AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1.
- chr9:4,490,468–6,008,482, 48 genes, copy number 8–20 (within-gene range 2–20): SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA.
- chr9:24,905,469–25,678,440, 4 genes, copy number 9: RMRPP5, RN7SKP120, AL353730.1, TUSC1.
- chr11:68,612,899–71,252,577, 65 genes, copy number 26–45 (broad region; genes not listed).
- chr13:37,854,852–39,603,528, 21 genes, copy number 7 (within-gene range 3–7): RNA5SP26, AL356495.1, LINC02334, HSPD1P9, LINC00571, UFM1, AL356863.1, LINC00437, LINC00366, PRDX3P3, FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1, LHFPL6.
- chr14:22,096,032–22,509,406, 65 genes, copy number 7 (broad region; genes not listed).
- chr16:82,491,738–83,800,640, 12 genes, copy number 7 (within-gene range 6–7): AC009117.2, CDH13, MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1, AC009142.1, MIR3182, AC009063.3, AC009063.4.
- chr19:37,545,470–40,690,972, 159 genes, copy number 13–24 (within-gene range 2–24) (broad region; genes not listed).
- chr19:44,631,573–45,092,635, 32 genes, copy number 13 (within-gene range 4–13): AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB, CLASRP, RNU6-611P, ZNF296, GEMIN7-AS1, GEMIN7.
- chr19:48,170,680–48,287,608, 7 genes, copy number 10 (within-gene range 2–10): ZSWIM9, CARD8, AC011466.4, AC011466.1, CARD8-AS1, ZNF114-AS1, ZNF114.
- chr19:48,954,815–51,564,910, 219 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr19:54,094,668–58,315,183, 298 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 458. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
